Somatic mutation profile of tumor specimen MP2PRT-PASTMJ-TMP1-A (aliquot MP2PRT-PASTMJ-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASTMJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,382 days).
Specimen MP2PRT-PASTMJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a9d02d7-73ab-4e0f-80ed-d5321ddfa519.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASTMJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASTMJ-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c009dd52-13c3-4e78-b779-759d7d6cfed7

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNK5 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 138/384 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, varscan2
- TRDN | c.1978G>C p.D660H | Missense Mutation (SNP) | VAF 11/280 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); called by muse, mutect2
- ANO1 | c.1866C>A p.I622= | Silent (SNP) | VAF 179/396 reads (45%) | catalogued as COSV60288500; called by muse, mutect2, varscan2
